Surgical pathology report (de-identified scan), TCGA case TCGA-CV-5979, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-5979-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

(A) PARTIAL GLOSSECTOMY

INVASIVE SQUAMOUS CARCINOMA -- Moderately differentiated

Tumor Features

Gross: Ulcerating

Size: 3 cm in largest dimension

Invasion: Present, depth 1.5 cm

Tumor Border: Infiltrative with thick cords > 4 cells

Perineural Invasion: Present, Focal

Vascular Invasion: Present

Lymphocyte Infiltration: Moderate

Mucosal Margin: negative

Deep Margin: Negative for invasive carcinoma

(B) LEFT NECK DISSECTION

METASTATIC CARCINOMA IN ONE OF THIRTY-FIVE LYMPH NODES (1/35)

LEVEL I:

Five lymph nodes, no tumor present (0/5).

LEVEL II:

METASTATIC CARCINOMA IN ONE ELEVEN LYMPH NODES (1/11).

LEVEL III:

Five lymph nodes, no tumor present (0/5).

LEVEL VI:

Four lymph nodes, no tumor present (0/4).

Salivary gland, no tumor present

(C) LEFT NECK SKIN TAG

Skin tag

Entire report and diagnosis completed by [REDACTED]

GROSS DESCRIPTION

(A) PARTIAL GLOSSECTOMY - A partial glossectomy specimen consisting of portion of tongue (10.0 x 6.0 x 3.0 cm).

There is a left floor of mouth lesion (3.0 x 2.5 x 1.5 cm) that is tan-white and 1.5 cm from the deep margin and 1.0 cm from the lateral margin. The surrounding mucosa is unremarkable. The above gross description is per Dr [REDACTED] and sections are taken by Dr [REDACTED]

SECTION CODE: A1-A11, entire lesion from anterior to posterior; A12-A16, representative sections of normal mucosa

*FS/DX. MARGINS FREE OF TUMOR. [REDACTED]

[page 2 of 2]
[REDACTED]

(B) LEFT NECK DISSECTION, LEVEL I, SUPERIOR CORE - A neck dissection specimen (16.0 x 13.0 x 2.0 cm) consisting of levels I through superior level IV according to the surgeon. An intact unremarkable salivary gland in level I (3.2 x 2.2 x 1.3 cm) is present. Multiple lymph nodes ranging from 0.2 cm to 4.0 cm are identified and entirely submitted.

SECTION CODE: B1, B2, salivary gland, level I; B3, one lymph node, level I; B4, five possible lymph nodes, level I; B5, four possible lymph nodes, level I; B6, one lymph node, bisected, level II; B7, one lymph node, bisected, level II; B8, five possible lymph nodes, level II; B9, three possible lymph nodes, level II; B10, one lymph node, bisected, level II; B11-B13, one lymph node, serially sectioned, level II; B14, two possible lymph nodes, level II; B15, four possible lymph nodes, level III; B16, five possible lymph nodes, level III; B17, three possible lymph nodes, level III; B18, four possible lymph nodes, level III; B19, three possible lymph nodes, level IV; B20, five possible lymph nodes, level IV. [REDACTED]

(C) LEFT NECK SKIN TAG - A portion of tan, round, gray piece of tissue (0.3 x 0.2 x 0.2 cm), which is bisected and entirely submitted.

SECTION CODE: C, entirely submitted [REDACTED]

CLINICAL HISTORY

None given

SNOMED CODES

M-80703, M-43000, T-53000

Some tests reported here may have been developed and performance characteristics determined by [REDACTED] Pathology and Laboratory Medicine. These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration.

Released by [REDACTED]

Source: NCI Genomic Data Commons file 1ba4e331-02fb-4098-b4a7-1e8ead1031e9 (TCGA-CV-5979.3A80F089-C70B-41BD-A513-19A2971D962C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).